Gene-level copy-number profile of tumor specimen SM-JU32Q from CPTAC case C289419, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU32Q: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4ef76212-2049-4ce7-bc56-eaa30bf9e034.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105213 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/6897f319-7400-45d2-b65b-715f97590050

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 121; copy number 1: 12,094; copy number 2: 43,356; copy number 3: 3,321; copy number 4: 7; copy number 15: 4; copy number 16: 4; copy number 18: 5; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 121 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,915,871–7,943,165, 2 genes: TNFRSF9, AL009183.1.
- chr1:16,440,721–16,536,172, 9 genes: NECAP2, LINC01772, CROCCP3, RNU1-1, AL137802.2, AL137802.3, AL137802.1, LINC01783, RNU1-6P.
- chr4:147,916,529–147,917,386, 1 gene (within-gene range 0–1): AC115621.1.
- chr4:148,445,703–149,024,624, 3 genes (within-gene range 0–1): AC002460.2, ASS1P8, RNA5SP166.
- chr4:148,819,351–149,154,175, 5 genes: AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430.
- chr4:149,789,952–149,790,303, 1 gene (within-gene range 0–1): AKIRIN2P1.
- chr9:21,524,307–23,682,662, 28 genes (within-gene range 0–1): SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr9:23,894,990–23,898,054, 1 gene: AL365204.2.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr14:18,667,249–19,957,996, 66 genes (broad region; genes not listed).
- chr14:23,938,219–24,052,555, 4 genes (within-gene range 0–1): DHRS4-AS1, DHRS4, DHRS4L2, AL136419.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,878,835–8,909,904, 5 genes, copy number 18 (within-gene range 1–18): ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2.
- chr1:9,292,894–9,503,471, 4 genes, copy number 15: SPSB1, LINC02606, RNA5SP40, AL928921.1.
- chr1:9,588,911–9,729,114, 5 genes, copy number 16–21 (within-gene range 1–21): TMEM201, PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2.

Autosomal genes at a single copy (total copy number 1): 9,238. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
